Somatic mutation profile of tumor specimen TCGA-D6-6517-01A (aliquot TCGA-D6-6517-01A-11D-1870-08) from TCGA case TCGA-D6-6517, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 59.7 years (21,791 days).
Specimen TCGA-D6-6517-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1233dfb-5686-4e67-8f44-b91e4f2c1a6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-6517-10A (Blood Derived Normal), aliquot TCGA-D6-6517-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0191098-a6bd-46b1-b2ee-73ab79ab87b1

The open-access MAF lists 72 somatic variants for this specimen: 53 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 17, Frame Shift Ins 4, In Frame Ins 1, Nonsense Mutation 1, Splice Region 1, Frame Shift Del 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 12/124 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACYP1 | c.184A>G p.M62V | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV99464867; called by muse, mutect2, varscan2
- AK4 | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519782; called by mutect2, varscan2
- ATF1 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); catalogued as rs1482170814, COSV100015994; called by muse, mutect2, varscan2
- CCSER1 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100388135; called by muse, mutect2, varscan2
- CIART | c.167G>C p.R56P | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV51743813, COSV99290071; called by muse, mutect2
- COL4A2 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs369462083; called by muse, mutect2, varscan2
- CSMD1 | c.1417G>A p.G473R (on ENST00000520002; = p.G472R on NM_033225.6) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101214112; called by muse, mutect2, varscan2
- EPHB2 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.738); catalogued as rs1332461819, COSV101006762; called by muse, mutect2, varscan2
- ERBB4 | c.2418G>C p.E806D | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100723582, COSV100725817; called by muse, mutect2, varscan2
- FAM155A | c.935T>A p.L312H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101026834; called by muse, mutect2, varscan2
- FOXB1 | c.322C>A p.R108S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101249668; called by muse, mutect2, varscan2
- FOXJ2 | c.822T>A p.F274L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.878); catalogued as COSV99368118; called by muse, varscan2
- GJC1 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100395125; called by muse, mutect2, varscan2
- GPR22 | c.356A>G p.E119G | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99771414; called by muse, mutect2, varscan2
- GRM8 | c.689G>A p.S230N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV100280841; called by muse, mutect2, varscan2
- GTF2E1 | c.273C>G p.Y91* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99381738, COSV99382303; called by muse, mutect2, varscan2
- IDO1 | c.1199T>G p.L400W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99503176; called by muse, mutect2
- IGKV3-20 | c.323A>T p.Y108F | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs759120046; called by muse, varscan2
- KIAA1549L | c.673G>C p.E225Q (on ENST00000321505; = p.E522Q on NM_012194.3) | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV99682655; called by muse, mutect2, varscan2
- KRT31 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs528644388, COSV99289406; called by muse, mutect2, varscan2
- LATS1 | c.2300G>T p.R767L | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53591194, COSV99485318; called by muse, mutect2, varscan2
- LCLAT1 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100092064; called by muse, mutect2, varscan2
- MARK3 | c.1630A>G p.I544V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99357819; called by muse, mutect2, varscan2
- MOGS | c.1376T>C p.V459A | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV99270304; called by mutect2, varscan2
- OR12D2 | c.635C>T p.T212I | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.116); catalogued as COSV101011107; called by muse, mutect2, varscan2
- OTOGL | c.1909G>A p.E637K (on ENST00000547103; = p.E628K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101509023; called by muse, mutect2, varscan2
- PCDH10 | c.1520T>C p.I507T | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs756657017, COSV99993004; called by muse, mutect2, varscan2
- PDCD11 | c.4707G>A p.T1569= | Splice Region (SNP) | VAF 10/52 reads (19%) | catalogued as rs760657326, COSV53297689; called by muse, mutect2, varscan2
- PICALM | c.70A>C p.K24Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100707713; called by muse, mutect2, varscan2
- PKIG | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV63069108; called by muse, mutect2, varscan2
- REEP1 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99382486; called by muse, mutect2, varscan2
- RIC8B | c.1420G>T p.D474Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100822443, COSV62693396; called by muse, mutect2
- SGK3 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.893); catalogued as COSV100616582; called by muse, mutect2, varscan2
- SLC18A3 | c.635G>C p.R212P | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs1414069827, COSV100339771, COSV60334934; called by muse, mutect2, varscan2
- SLC25A22 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV100204102; called by mutect2, varscan2
- SLC2A12 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99259643; called by muse, mutect2, varscan2
- SLC38A7 | c.1106G>T p.R369L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.998); catalogued as COSV54705151, COSV99543582; called by mutect2, varscan2
- SNX25 | c.2386A>G p.I796V | Missense Mutation (SNP) | VAF 65/286 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV99252392; called by muse, mutect2, varscan2
- STAB1 | c.7179C>A p.N2393K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100194546; called by muse, mutect2, varscan2
- TACR2 | c.242G>A p.C81Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100964779; called by muse, mutect2, varscan2
- TAS2R1 | c.185T>C p.I62T | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); catalogued as rs778995507, COSV101225696; called by muse, mutect2, varscan2
- TLN2 | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs200753658, COSV100168028; called by muse, mutect2, varscan2
- TRMT13 | c.223C>A p.H75N | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99790597; called by muse, mutect2, varscan2
- VPS52 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146611103; called by muse, mutect2, varscan2
- WIPF1 | c.421T>C p.F141L | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV99767956; called by muse, mutect2
- ZBTB25 | c.604del p.S202Pfs*12 | Frame Shift Del (DEL) | VAF 53/254 reads (21%) | catalogued as rs1566599986; called by mutect2, pindel, varscan2
- FAT1 | c.1186dup p.S396Ffs*8 | Frame Shift Ins (INS) | VAF 26/123 reads (21%) | called by mutect2, pindel, varscan2
- NRDC | c.3273_3274insGG p.L1092Gfs*2 | Frame Shift Ins (INS) | VAF 11/71 reads (15%) | called by mutect2, pindel, varscan2
- RBM15 | c.2571dup p.A858Cfs*11 | Frame Shift Ins (INS) | VAF 39/145 reads (27%) | called by mutect2, pindel, varscan2
- TGOLN2 | c.226_228dup p.T76dup | In Frame Ins (INS) | VAF 30/294 reads (10%) | called by mutect2, pindel
- ZNF687 | c.2135dup p.M712Ifs*17 | Frame Shift Ins (INS) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- ABRA | c.267T>C p.H89= | Silent (SNP) | VAF 13/159 reads (8%) | catalogued as COSV100357462; called by muse, mutect2
- ARFGEF2 | c.1713C>T p.L571= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100903991; called by muse, mutect2
- BCORL1 | c.549C>A p.V183= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs779045172, COSV99498510; called by muse, mutect2, varscan2
- DDX58 | c.873G>A p.G291= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV101152483; called by muse, mutect2, varscan2
- ERICH3 | c.1221G>A p.P407= | Silent (SNP) | VAF 26/152 reads (17%) | catalogued as rs539368276, COSV58602813; called by muse, mutect2, varscan2
- H2AC11 | c.144G>T p.A48= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV100345602; called by muse, mutect2, varscan2
- MAOA | c.738C>T p.H246= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as rs1326709993, COSV100108610, COSV58641303; called by muse, mutect2, varscan2
- MC5R | c.685C>A p.R229= | Silent (SNP) | VAF 37/183 reads (20%) | catalogued as rs1002328102, COSV100228931, COSV61255817; called by muse, mutect2, varscan2
- MEPE | c.27C>T p.L9= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as COSV100734849; called by muse, mutect2, varscan2
- NIM1K | c.981G>C p.G327= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV100389921; called by muse, mutect2, varscan2
- OR10R2 | c.435C>T p.A145= | Silent (SNP) | VAF 50/267 reads (19%) | catalogued as COSV100936760; called by muse, mutect2, varscan2
- OR5AK2 | c.555T>G p.L185= | Silent (SNP) | VAF 51/304 reads (17%) | catalogued as COSV100475897; called by muse, mutect2, varscan2
- OR5D18 | c.462C>G p.V154= | Silent (SNP) | VAF 36/185 reads (19%) | catalogued as COSV100450515; called by muse, mutect2, varscan2
- PER1 | c.2517C>T p.A839= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV100424272; called by mutect2, varscan2
- RITA1 | c.138G>A p.R46= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100013600; called by muse, mutect2, varscan2
- SIGLEC6 | c.936A>C p.A312= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100585160; called by muse, mutect2, varscan2
- TEX15 | c.3039A>G p.T1013= (on ENST00000256246; = p.T1396= on NM_001350162.2) | Silent (SNP) | VAF 49/162 reads (30%) | catalogued as rs201665635; called by muse, mutect2, varscan2
- ZNF137P | n.1662T>A | RNA (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- ZNF99 | c.*17A>C | 3'UTR (SNP) | VAF 15/77 reads (19%) | catalogued as COSV101233712; called by muse, mutect2, varscan2
